Surgical pathology report (de-identified scan), TCGA case TCGA-FA-A86F, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-A86F-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: Two lymph nodes 2x1.4cm and 1cm in size, soft and hyperemic.

Microscopic Description: Morphological picture in favor of Non-Hodgkin's Large B-cell lymphoma with partial lesion of adjacent lymph node, which was probably localized on the side of malignant process.

Cytokeratin pan (AE1 and AE3) - negative

Melanosome (HMB-45)- negative

CD 45 (PD7/26) - positive reaction in tumor cells

Chromogranin A (DAK-A3) - negative

CD 20cy (L26) - positive reaction in tumor cells

CD 3 (PS1) - negative reaction in tumor cells

CD 10 (56C6) - negative reaction in tumor cells, positive reaction in follicular centers

Ki67 Protein (MIB-1) - up to 40% in tumor cells

Diagnosis Details: Tumor Features: -1, Tumor Extent: Involvement of a single lymph node region,
Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: Lymph node tumor checklist

Diagnosis: Diffuse large B-cell lymphoma of the lymph node

Tumor size: 1.4 x 0 x 2 cm

Tumor location: Lymph node, axillary

Tumor grade: Unspecified

Margins: Uninvolved

Venous invasion: Absent

Tumor extent: Unspecified

Diagnosis details: IHC:

ICD-O-3
Lymphoma, diffuse large B cell
9880/3
Site lymph node
77.3
JW 4/11/14

[page 2 of 2]
Cytokeratin pan (AE1 and AE3) - negative

Melanosome (HMB-45)- negative

CD 45 (PD7/26) - positive reaction in tumor cells

Chromogranin A (DAK-A3) - negative

CD 20cy (L26) - positive reaction in tumor cells

CD 3 (PS1) - negative reaction in tumor cells

CD 10 (56C6) - negative reaction in tumor cells, positive reaction in follicular centers

Ki67 Protein (MIB-1) - up to 40% in tumor cells

Comments: None

Source: NCI Genomic Data Commons file fdaf1456-5b5b-4d25-8837-0224520a0e72 (TCGA-FA-A86F.6D34FB3F-83A5-4B8D-AB2A-76931ED85F9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).